Somatic mutation profile of tumor specimen TCGA-EL-A4K0-01A (aliquot TCGA-EL-A4K0-01A-11D-A257-08) from TCGA case TCGA-EL-A4K0, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 54.9 years (20,042 days).
Specimen TCGA-EL-A4K0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2532225a-6bae-4e8f-94ee-f42d1d20ab0c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A4K0-11A (Solid Tissue Normal), aliquot TCGA-EL-A4K0-11A-11D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fa449b22-cf4d-4464-8d99-0b1cfaec2d9a

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Intron 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ARCN1 | c.748A>G p.M250V | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV50615004; called by muse, mutect2, varscan2
- BCKDK | c.716G>T p.R239I | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); catalogued as COSV54891899; called by muse, mutect2, varscan2
- GPC6 | c.547A>C p.S183R | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); catalogued as COSV65510687; called by muse, mutect2, varscan2
- HMCN1 | c.8843C>A p.T2948K | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.97); PolyPhen probably damaging (0.967); catalogued as COSV54898777; called by muse, mutect2, varscan2
- LCE1C | c.44A>T p.K15M | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.759); catalogued as COSV64218423; called by muse, mutect2, varscan2
- SETD5 | c.755C>T p.T252I | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV56710743; called by muse, mutect2, varscan2
- SSX1 | c.235T>A p.F79I | Missense Mutation (SNP) | VAF 66/175 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.075); catalogued as COSV65355491; called by muse, mutect2, varscan2
- NRROS | c.834G>C p.L278= | Silent (SNP) | VAF 35/138 reads (25%) | catalogued as COSV60745788; called by muse, mutect2, varscan2
- NELL2 | c.56-162del | Intron (DEL) | VAF 6/21 reads (29%) | called by mutect2, pindel, varscan2
- TTN | c.34264+578A>G | Intron (SNP) | VAF 57/195 reads (29%) | catalogued as COSV100627502; called by muse, mutect2, varscan2
